Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3984, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3984-01A (Primary Tumor).

locally R0, additionally a villous adenoma with focally severe dysplasia (intraepithelial neoplasia of the high-risk type) and a serrated adenoma and free lymph nodes (pN0).

Source: NCI Genomic Data Commons file 51fcd120-88ba-427c-94f4-65ac4abc76d3 (TCGA-AA-3984.A1027D0E-BF96-45B2-A762-E71F3A5563DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).